Somatic mutation profile of tumor specimen C3L-02610-03 (aliquot CPT0124980007_1) from CPTAC case C3L-02610, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 80.9 years (29,536 days).
Specimen C3L-02610-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b10fcafa-9ea7-4a25-8564-3004fe5ef1b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02610-31 (Blood Derived Normal), aliquot CPT0125020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d3a78f4-b090-439e-9d13-4ee23983477b

The open-access MAF lists 61 somatic variants for this specimen: 37 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 19, Frame Shift Ins 2, 3'Flank 1, Intron 1, Splice Site 1, Frame Shift Del 1, 5'UTR 1, 3'UTR 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 110/438 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 90/634 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as CM056067, CM920671, CM942120, COSV52675795, COSV52676870, COSV52730435, COSV53567603; called by muse, mutect2, varscan2
- CDKN2A | c.47_50del p.L16Pfs*9 | Frame Shift Del (DEL) | VAF 42/392 reads (11%) | catalogued as rs587782206; called by pindel, varscan2
- CENPE | c.5934dup p.E1979Rfs*6 | Frame Shift Ins (INS) | VAF 12/110 reads (11%) | catalogued as rs1350400778; called by mutect2, pindel
- CLEC18A | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 4/515 reads (1%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs764034494; called by muse, mutect2
- CNTN6 | c.2398G>T p.D800Y | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63192865; called by muse, mutect2
- COLEC11 | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 98/1102 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.519); catalogued as COSV99363298; called by muse, mutect2
- CSMD1 | c.548T>A p.L183Q | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460363308, COSV101213984; called by muse, mutect2, varscan2
- DCLK1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 55/525 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1566022803, COSV55191105; called by muse, mutect2
- DNAH9 | c.796T>A p.Y266N | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV52356054; called by muse, mutect2
- FAM240A | c.55C>T p.R19C (on ENST00000444264; = p.R13C on NM_001195442.2) | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs766427639; called by muse, mutect2, varscan2
- GIMAP8 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs749652932, COSV56230970; called by muse, mutect2, varscan2
- IL21R | c.432C>A p.D144E | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs949248876; called by muse, mutect2
- KNDC1 | c.2183C>A p.T728K | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as COSV58831384; called by muse, mutect2
- MKRN3 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs779114986, COSV58809720; called by muse, mutect2
- MPP7 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200656300; called by muse, mutect2, varscan2
- PDZRN4 | c.3052G>A p.A1018T (on ENST00000402685 / NM_001164595.2; = p.A760T on NM_013377.4) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.031); catalogued as COSV100114636; called by muse, mutect2
- RNF43 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs748533737, COSV68458461; called by muse, mutect2, varscan2
- SMAD4 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 89/492 reads (18%) | catalogued as COSV61686461, COSV61695955; called by muse, mutect2, varscan2
- SMOC1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs376548937; called by muse, mutect2, varscan2
- TMEM121 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as rs960108232; called by muse, mutect2, varscan2
- ZNF610 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs768546961; called by muse, mutect2, varscan2
- ARVCF | c.2645G>A p.G882D | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.06); called by muse, mutect2
- C11orf95 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 27/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDT1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 92/611 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRACD | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 59/589 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- GML | c.73+2T>C p.X25_splice | Splice Site (SNP) | VAF 26/335 reads (8%) | called by muse, mutect2
- GNAI2 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); called by muse, mutect2
- GSG1L | c.245dup p.G83Wfs*36 | Frame Shift Ins (INS) | VAF 28/247 reads (11%) | called by mutect2, pindel, varscan2
- LAMA4 | c.5182G>T p.D1728Y (on ENST00000230538 / NM_001105206.3; = p.D1721Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/650 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTERF1 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- MUC17 | c.935C>G p.A312G | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2
- MYH6 | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- PDS5B | c.4090A>C p.I1364L | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- POSTN | c.2302G>A p.G768R | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.258); called by muse, mutect2
- STARD9 | c.12895C>A p.L4299I | Missense Mutation (SNP) | VAF 43/449 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- TRIM35 | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ACTL8 | c.327G>A p.A109= | Silent (SNP) | VAF 17/183 reads (9%) | catalogued as rs765307312, COSV64861016; called by muse, mutect2
- ADAM19 | c.2490G>A p.S830= | Silent (SNP) | VAF 45/342 reads (13%) | catalogued as rs764968777, COSV57427459; called by muse, mutect2, varscan2
- C22orf31 | c.606G>A p.T202= | Silent (SNP) | VAF 58/455 reads (13%) | catalogued as rs776057378, COSV53310737; called by muse, mutect2, varscan2
- CCDC30 | c.2352T>C p.S784= (on ENST00000340612; = p.S741= on NM_001080850.3) | Silent (SNP) | VAF 40/421 reads (10%) | catalogued as rs765865782; called by muse, mutect2
- CCT6B | c.117T>C p.G39= | Silent (SNP) | VAF 23/168 reads (14%) | called by mutect2, varscan2
- CECR2 | c.3387G>A p.T1129= (on ENST00000342247 / NM_001290047.2; = p.T945= on NM_001290046.1) | Silent (SNP) | VAF 62/491 reads (13%) | catalogued as rs751868810; called by muse, mutect2, varscan2
- DMXL1 | c.8157C>T p.G2719= | Silent (SNP) | VAF 32/278 reads (12%) | catalogued as rs751162158; called by muse, mutect2, varscan2
- ERGIC3 | c.744C>T p.H248= | Silent (SNP) | VAF 32/302 reads (11%) | called by muse, mutect2, varscan2
- F10 | c.1215C>T p.A405= | Silent (SNP) | VAF 97/880 reads (11%) | catalogued as rs770904651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXH1 | c.445C>T p.L149= | Silent (SNP) | VAF 134/685 reads (20%) | called by muse, mutect2, varscan2
- FZD9 | c.678C>A p.R226= | Silent (SNP) | VAF 88/386 reads (23%) | called by muse, mutect2, varscan2
- HMX1 | c.894C>T p.P298= | Silent (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- INPPL1 | c.1608C>T p.N536= | Silent (SNP) | VAF 38/324 reads (12%) | called by muse, mutect2, varscan2
- OR4K2 | c.264T>C p.G88= | Silent (SNP) | VAF 35/682 reads (5%) | called by muse, mutect2
- OR51V1 | c.819C>T p.P273= | Silent (SNP) | VAF 30/281 reads (11%) | catalogued as rs142226521; called by muse, mutect2, varscan2
- PDZRN3 | c.714C>T p.P238= | Silent (SNP) | VAF 29/240 reads (12%) | catalogued as rs576789805; called by muse, mutect2, varscan2
- SLC2A12 | c.1470C>T p.I490= | Silent (SNP) | VAF 34/331 reads (10%) | called by muse, varscan2
- SPTBN2 | c.5901C>T p.I1967= | Silent (SNP) | VAF 237/1020 reads (23%) | catalogued as rs200009167; called by muse, mutect2, varscan2
- ZNF300 | c.1254C>T p.F418= | Silent (SNP) | VAF 23/221 reads (10%) | called by muse, mutect2, varscan2
- A2M | c.-15C>A | 5'UTR (SNP) | VAF 128/602 reads (21%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848459 T>A | 5'Flank (SNP) | VAF 34/131 reads (26%) | called by muse, mutect2, varscan2
- HROB | c.*13G>A | 3'UTR (SNP) | VAF 25/190 reads (13%) | catalogued as rs776450660; called by muse, mutect2, varscan2
- MTX1 | chr1:155215119 G>A | 3'Flank (SNP) | VAF 109/1023 reads (11%) | called by muse, mutect2, varscan2
- PRRX1 | c.599+3899G>T | Intron (SNP) | VAF 37/423 reads (9%) | called by muse, mutect2
